Somatic mutation profile of tumor specimen ALCH-B38E-TTP1-A (aliquot ALCH-B38E-TTP1-A-1-0-D-A780-36) from ALCHEMIST case ALCH-B38E, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.6 years (24,324 days).
Specimen ALCH-B38E-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01ca2a5f-cd75-465e-a8c4-ae5907744f6f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B38E-NB1-A (Blood Derived Normal), aliquot ALCH-B38E-NB1-A-1-0-D-A780-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d6d6b6f-7a9f-42a5-8996-618348ab515a

The open-access MAF lists 101 somatic variants for this specimen: 74 protein-altering or splice-affecting, 17 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 17, Nonsense Mutation 4, Intron 3, RNA 3, Splice Site 2, 5'UTR 2, 3'UTR 1, 5'Flank 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 48/180 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMDEC1 | c.599G>T p.R200L | Missense Mutation (SNP) | VAF 60/320 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.057); catalogued as COSV56474101; called by muse, mutect2, varscan2
- AL035460.1 | c.508T>C p.C170R | Missense Mutation (SNP) | VAF 35/234 reads (15%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as rs1206153362; called by muse, mutect2, varscan2
- ATP4A | c.1605G>C p.K535N | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52869790; called by muse, mutect2, varscan2
- BAHCC1 | c.5072C>T p.S1691F | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1416721859; called by muse, mutect2, varscan2
- C10orf53 | c.16G>A p.V6M | Missense Mutation (SNP) | VAF 42/305 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.168); catalogued as rs901025591; called by muse, mutect2, varscan2
- CCDC33 | c.1258G>C p.E420Q | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.117); catalogued as COSV58354658; called by muse, mutect2, varscan2
- CDH12 | c.326G>T p.G109V | Missense Mutation (SNP) | VAF 38/320 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66427479; called by muse, mutect2, varscan2
- CLPTM1 | c.1975C>T p.P659S | Missense Mutation (SNP) | VAF 65/277 reads (23%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV61610879; called by muse, mutect2, varscan2
- DCAF8L1 | c.1201G>A p.D401N | Missense Mutation (SNP) | VAF 52/311 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.155); catalogued as rs1310904525, COSV71595267; called by muse, mutect2, varscan2
- DSC1 | c.475C>A p.Q159K | Missense Mutation (SNP) | VAF 29/214 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1173027586; called by muse, mutect2, varscan2
- FCAMR | c.812C>G p.T271S | Missense Mutation (SNP) | VAF 31/236 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.068); catalogued as COSV61369133; called by muse, mutect2, varscan2
- GPIHBP1 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM147083; called by muse, mutect2, varscan2
- GPR78 | c.56C>A p.A19E | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV66763155; called by muse, mutect2
- IARS2 | c.2488A>G p.I830V | Missense Mutation (SNP) | VAF 79/288 reads (27%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as rs961332345; called by muse, mutect2, varscan2
- ITGAD | c.3155G>A p.R1052H | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.298); catalogued as rs535493782; called by muse, mutect2, varscan2
- MS4A12 | c.446C>A p.A149E | Missense Mutation (SNP) | VAF 37/228 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV50014710; called by muse, mutect2, varscan2
- OR2C3 | c.56C>G p.S19C | Missense Mutation (SNP) | VAF 26/176 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV100825720; called by muse, mutect2
- SLITRK2 | c.381G>T p.E127D | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT tolerated (0.79); PolyPhen benign (0.066); catalogued as COSV100158039; called by muse, mutect2, varscan2
- TRAV21 | c.173A>G p.D58G | Missense Mutation (SNP) | VAF 106/420 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.313); catalogued as rs1156399086; called by muse, mutect2, varscan2
- ZNF347 | c.1490A>G p.H497R | Missense Mutation (SNP) | VAF 36/213 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV100498412; called by muse, mutect2, varscan2
- ZNF835 | c.1411G>T p.E471* | Nonsense Mutation (SNP) | VAF 46/276 reads (17%) | catalogued as rs771556208; called by muse, mutect2, varscan2
- ADGRL3 | c.166G>T p.E56* | Nonsense Mutation (SNP) | VAF 84/405 reads (21%) | called by muse, mutect2, varscan2
- AFAP1L1 | c.1417G>C p.G473R | Missense Mutation (SNP) | VAF 84/351 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- APOL5 | c.752C>A p.S251Y | Missense Mutation (SNP) | VAF 40/246 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- ATG16L2 | c.710+3A>T | Splice Region (SNP) | VAF 29/153 reads (19%) | called by muse, mutect2, varscan2
- ATRNL1 | c.2255G>T p.W752L | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CBX2 | c.865G>T p.D289Y | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- CCDC144A | c.4178G>T p.C1393F | Missense Mutation (SNP) | VAF 70/729 reads (10%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); called by muse, varscan2
- CGN | c.1401+3_1401+36del p.X467_splice | Splice Site (DEL) | VAF 41/150 reads (27%) | called by mutect2, pindel
- CNTNAP1 | c.890T>C p.L297P | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- COL2A1 | c.1988G>A p.G663E | Missense Mutation (SNP) | VAF 83/464 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CRLF2 | c.124G>T p.V42L | Missense Mutation (SNP) | VAF 37/261 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- CYP4F22 | c.643G>T p.V215F | Missense Mutation (SNP) | VAF 87/568 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- DRAXIN | c.53T>A p.L18Q | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- DSCAM | c.1084A>T p.I362F | Missense Mutation (SNP) | VAF 71/498 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.005); called by mutect2, varscan2
- EMC3 | c.639C>A p.D213E | Missense Mutation (SNP) | VAF 58/239 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- EPHA10 | c.1524G>T p.K508N | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- ERCC6L2 | c.3325G>C p.D1109H | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- FAM155B | c.925T>A p.W309R | Missense Mutation (SNP) | VAF 33/212 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GABRA6 | c.321G>A p.M107I | Missense Mutation (SNP) | VAF 76/365 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- GBA3 | c.947A>T p.Y316F | Missense Mutation (SNP) | VAF 37/187 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GIMAP5 | c.470G>T p.G157V | Missense Mutation (SNP) | VAF 36/190 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- HERC2 | c.10555-2A>T p.X3519_splice | Splice Site (SNP) | VAF 9/78 reads (12%) | called by muse, varscan2
- IL36RN | c.348C>G p.Y116* | Nonsense Mutation (SNP) | VAF 108/550 reads (20%) | called by muse, mutect2, varscan2
- KLHL14 | c.124C>G p.Q42E | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (1); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- KRT1 | c.1820G>T p.G607V | Missense Mutation (SNP) | VAF 46/256 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- KRT15 | c.677T>A p.L226Q | Missense Mutation (SNP) | VAF 59/309 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAGED1 | c.901G>T p.A301S | Missense Mutation (SNP) | VAF 56/215 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- MARK2 | c.422T>G p.L141R | Missense Mutation (SNP) | VAF 56/297 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- MAST4 | c.1401A>T p.Q467H (on ENST00000403625 / NM_001164664.2; = p.Q278H on NM_015183.3) | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MDC1 | c.1883G>T p.G628V | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MNX1 | c.1100A>C p.H367P | Missense Mutation (SNP) | VAF 42/241 reads (17%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- MTCL1 | c.1584G>C p.R528S (on ENST00000306329 / NM_001378206.1; = p.R168S on NM_015210.4) | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- MUC5B | c.127G>T p.G43C | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- MYO1E | c.2072G>T p.R691I | Missense Mutation (SNP) | VAF 47/252 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- NAA11 | c.532C>A p.Q178K | Missense Mutation (SNP) | VAF 65/311 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR2F2 | c.232G>A p.V78I | Missense Mutation (SNP) | VAF 41/224 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- P2RY8 | c.409C>G p.R137G | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- PLA2G4D | c.488G>A p.C163Y | Missense Mutation (SNP) | VAF 42/248 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- PLEC | c.3153C>A p.F1051L (on ENST00000322810 / NM_201380.4; = p.F941L on NM_000445.5) | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.76); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTPRH | c.1748T>A p.L583Q | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBM10 | c.1896del p.S633Rfs*71 | Frame Shift Del (DEL) | VAF 50/266 reads (19%) | called by mutect2, pindel, varscan2
- RETREG2 | c.400G>T p.E134* | Nonsense Mutation (SNP) | VAF 63/284 reads (22%) | called by muse, mutect2, varscan2
- RNF4 | c.329C>T p.T110I | Missense Mutation (SNP) | VAF 39/174 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- SLITRK2 | c.382G>T p.D128Y | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SNRPB | c.426G>T p.M142I | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- SUPT20HL1 | c.2435A>T p.Q812L | Missense Mutation (SNP) | VAF 61/278 reads (22%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TANC2 | c.3293A>T p.K1098M | Missense Mutation (SNP) | VAF 71/369 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TESPA1 | c.169C>G p.P57A | Missense Mutation (SNP) | VAF 35/254 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- TRAPPC10 | c.2570A>T p.Q857L | Missense Mutation (SNP) | VAF 50/215 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- UGGT1 | c.1811G>C p.S604T | Missense Mutation (SNP) | VAF 25/174 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- USP51 | c.367C>A p.P123T | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- VPS41 | c.1808A>T p.K603M | Missense Mutation (SNP) | VAF 48/239 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ACAN | c.6604C>T p.L2202= | Silent (SNP) | VAF 70/299 reads (23%) | catalogued as COSV61366185; called by muse, mutect2, varscan2
- ARMC5 | c.48C>T p.L16= | Silent (SNP) | VAF 31/187 reads (17%) | catalogued as COSV51655029, COSV51657963, COSV51659455; called by muse, mutect2, varscan2
- C16orf72 | c.432C>T p.I144= | Silent (SNP) | VAF 75/438 reads (17%) | called by muse, mutect2, varscan2
- CALCRL | c.1257G>A p.A419= | Silent (SNP) | VAF 53/276 reads (19%) | catalogued as rs146718835; called by muse, mutect2, varscan2
- CD5L | c.108G>T p.R36= | Silent (SNP) | VAF 33/203 reads (16%) | catalogued as COSV63822370; called by muse, mutect2
- DSG3 | c.2064T>A p.P688= | Silent (SNP) | VAF 30/249 reads (12%) | called by muse, mutect2, varscan2
- GET3 | c.15G>T p.V5= | Silent (SNP) | VAF 8/47 reads (17%) | called by muse, mutect2, varscan2
- ITGB3 | c.291C>T p.D97= | Silent (SNP) | VAF 79/368 reads (21%) | called by muse, mutect2, varscan2
- MUC12 | c.15699C>A p.V5233= (on ENST00000379442; = p.V5090= on NM_001164462.1) | Silent (SNP) | VAF 22/119 reads (18%) | catalogued as COSV59331190; called by muse, mutect2, varscan2
- MYRFL | c.282G>A p.A94= | Silent (SNP) | VAF 51/272 reads (19%) | called by muse, mutect2, varscan2
- OSGEP | c.279C>A p.A93= | Silent (SNP) | VAF 22/132 reads (17%) | called by muse, mutect2, varscan2
- PANK4 | c.549C>T p.H183= | Silent (SNP) | VAF 17/69 reads (25%) | called by muse, mutect2, varscan2
- RPS6KA5 | c.1791C>T p.N597= | Silent (SNP) | VAF 28/135 reads (21%) | catalogued as rs139792854, COSV56222323; called by muse, mutect2, varscan2
- SLITRK2 | c.2526C>T p.I842= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs1569507254, COSV59424247; called by muse, varscan2
- TCP11X2 | c.774G>T p.P258= | Silent (SNP) | VAF 112/1102 reads (10%) | called by muse, mutect2, varscan2
- TRPM8 | c.667C>A p.R223= | Silent (SNP) | VAF 85/483 reads (18%) | catalogued as rs762851956, COSV100224766, COSV61221931; called by muse, mutect2, varscan2
- TSHZ3 | c.279C>T p.I93= | Silent (SNP) | VAF 13/91 reads (14%) | called by muse, mutect2, varscan2
- AC136759.1 | n.1220G>A | RNA (SNP) | VAF 105/559 reads (19%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503658 del AAATA | 5'Flank (DEL) | VAF 10/54 reads (19%) | catalogued as rs764217042; called by pindel, varscan2
- CEP41 | c.*384G>T | 3'UTR (SNP) | VAF 91/516 reads (18%) | called by muse, mutect2, varscan2
- EIF2B5 | c.1893+24A>G | Intron (SNP) | VAF 61/281 reads (22%) | called by muse, mutect2, varscan2
- MIR892A | n.44T>A | RNA (SNP) | VAF 13/81 reads (16%) | called by muse, mutect2, varscan2
- MPO | c.-4A>G | 5'UTR (SNP) | VAF 18/152 reads (12%) | called by muse, mutect2, varscan2
- NEB | c.8890-3069G>A | Intron (SNP) | VAF 65/304 reads (21%) | called by muse, mutect2, varscan2
- SNORD114-14 | n.22C>T | RNA (SNP) | VAF 18/130 reads (14%) | catalogued as rs770951386; called by muse, mutect2, varscan2
- ST8SIA3 | c.-125G>A | 5'UTR (SNP) | VAF 3/38 reads (8%) | catalogued as rs1226304962; called by muse, mutect2
- TREM2 | c.483-18C>A | Intron (SNP) | VAF 34/236 reads (14%) | called by muse, mutect2, varscan2
